Somatic mutation profile of tumor specimen MP2PRT-PASMXV-TMP1-A (aliquot MP2PRT-PASMXV-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASMXV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,598 days).
Specimen MP2PRT-PASMXV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a8c5c4e-7a6e-4c1c-9992-6362bdb87674.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMXV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMXV-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3b88384-d330-4912-92e2-0ace996fa997

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, 5'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CGB2 | c.12G>A p.G4= | Splice Region (SNP) | VAF 54/454 reads (12%) | catalogued as rs1275000963; called by muse, mutect2, varscan2
- FLT3 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by mutect2, varscan2
- KCNA4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs768852661, COSV60251924, COSV60255631; called by muse, mutect2, varscan2
- MYC | c.173C>A p.T58N (on ENST00000377970; = p.T73N on NM_002467.6) | Missense Mutation (SNP) | VAF 383/826 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52367994, COSV52373588; called by muse, mutect2, varscan2
- SGSM1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 43/924 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768962451, COSV68509585; called by muse, mutect2
- ARHGAP29 | c.2725A>C p.K909Q | Missense Mutation (SNP) | VAF 186/416 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- C1orf141 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FREM2 | c.3614G>T p.S1205I | Missense Mutation (SNP) | VAF 182/421 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- IKZF1 | c.786_787insTG p.V263Wfs*6 | Frame Shift Ins (INS) | VAF 175/478 reads (37%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.5720G>T p.G1907V | Missense Mutation (SNP) | VAF 268/556 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP53 | c.1248T>G p.A416= | Silent (SNP) | VAF 131/330 reads (40%) | called by muse, mutect2, varscan2
- ESYT2 | c.1005G>A p.T335= (on ENST00000613624; = p.T259= on NM_020728.3) | Silent (SNP) | VAF 259/563 reads (46%) | catalogued as rs140480085; called by muse, mutect2, varscan2
- MECOM | c.315G>A p.K105= | Silent (SNP) | VAF 186/471 reads (39%) | called by muse, mutect2, varscan2
- PDE7B | c.453T>C p.D151= | Silent (SNP) | VAF 176/382 reads (46%) | called by muse, varscan2
- TSHZ3 | c.2061G>A p.P687= | Silent (SNP) | VAF 57/816 reads (7%) | catalogued as rs200176289; called by muse, mutect2
- CDC14A | chr1:100351796 A>C | 5'Flank (SNP) | VAF 29/511 reads (6%) | called by muse, mutect2
